TARGET case TARGET-20-KasumiAZAD11 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/28f7e68c-e0ab-4fb0-b835-2e506cb0012d

Biospecimens (1 sample)
- Sample TARGET-20-KasumiAZAD11-50A: Sample type: Cell Lines; Tissue type: Tumor; Specimen type: Derived Cell Line.
